Surgical pathology report (de-identified scan), TCGA case TCGA-91-6849, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-6849-01A (Primary Tumor).

[page 1 of 4]
Final Pathologic Diagnosis:

A. Lymph node, left lung #6 anterior and anterior left, lymphadenectomy:

Eight of twelve lymph nodes positive for metastatic adenocarcinoma.

Largest focus 0.4 cm.

No extranodal extension.

Extensive sinus histiocytosis and anthracosis.

B. Lymph node, left hilar, lymphadenectomy:

One lymph node with anthracosis and sinus histiocytosis.

No evidence of metastatic carcinoma.

C. Lymph node, left lung #10 tracheobronchial, lymphadenectomy:

Four of four lymph nodes positive for metastatic adenocarcinoma.

Largest focus 0.6 cm.

No extranodal extension.

D. Lung, left upper lobe, lobectomy:

Tumor histologic type: Invasive adenocarcinoma with peripheral bronchioloalveolar .

Size of invasive tumor: 5.0 x 4.1 x 2.4 cm.

Grade: Moderately to poorly differentiated.

Lymphovascular invasion: Present, extensive.

Pleura: Invasion into but not through the pleura.

Bronchial resection margin: Free of malignancy (frozen section diagnosis confirmed).

Lymph nodes: Direct extension into two intraparenchymal lymph nodes.

Metastasis to two peribronchial lymph nodes, largest focus 1.0 cm, no extranodal extension.

Other findings: Emphysema.

E. Lung, left lower lobe anterior basal tissue, wedge biopsy:

Adenocarcinoma, 1.0 cm, moderately to poorly differentiated, similar features as the left upper lobe tumor.

No evidence of transpleural extension.

Peripheral bronchioloalveolar features.

Sampled margins free of malignancy.

Hyalinized and calcified granuloma.

F. Lymph node, left lung AP window, lymphadenectomy:

Two of two lymph nodes positive for metastatic adenocarcinoma.

Largest focus 0.6 cm.

No extranodal extension.

AJCC Cancer Stage: Larger tumor upper lobe: T2, N2, MX

Smaller tumor lower lobe: T1, N2, MX

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Electronically Signed

, [REDACTED]

Intraoperative Consult Diagnosis:

FSD: Left upper lobe, bronchial margin:

Negative for malignancy.

[page 2 of 4]
F/S TAT: 15 mins.

Gross Description:

Received are six containers labeled with the patient name " ."

The first is received with formalin labeled "A-left lung #6 anterior and anterior left lymph nodes," and contains ten grossly apparent whole lymph nodes ranging in size from 0.3 to 1.8 cm in diameter. The specimen is submitted entirely in the following manner:

- A1 four whole lymph nodes;
- A2 four whole lymph nodes;
- A3 two whole lymph nodes.

The second container is received with formalin labeled "B-hilar left lymph node," and contains a single probable lymph node measuring 0.5 cm in greatest dimension. The specimen is submitted in toto in a single cassette labeled B1.

The third container is received with formalin labeled "C-left lung #10 tracheobronchial node," and contains four grossly apparent lymph nodes ranging in size from 0.3 to 1.4 cm in greatest dimension. The specimen is submitted entirely in the following manner:

- C1 one largest lymph node bisected;
- C2 three possible small lymph nodes.

The fourth container is received without formalin for intraoperative frozen section consultation labeled "D-left upper lobe bronchial margin," and contains a lobectomy specimen measuring 14.5 x 9.5 x 3.2 cm. The bronchial margin is left open. The bronchial margin is trimmed and submitted for frozen section diagnosis, with the residual tissue now resubmitted for permanent section in cassette D1. The pleural surface is blue-gray and smooth-glistening with a reticular pattern of black pigmentation. The pleura is somewhat fibrotic and puckered in one area, overlying a palpable mass. The lung parenchyma is stapled in three short segments near the hilum. Each of these three segments is trimmed and the resulting cut surface is inked black. Sectioning through the lung reveals a mass measuring 5.0 x 4.1 x 2.4 cm involving the above noted pleural surface. The mass has a heterogeneous white-tan, fibrous cut surface with speckling of black pigmentation. The mass approaches up to the pleural surface.

Two lymph nodes are present at the bronchial hilum measuring 0.4 and 1.2 cm in diameter. The mass appears grossly to be confluent with possible intraparenchymal lymph nodes. Representative sections are submitted in the following manner:

- D1 bronchial margin;
- D2 two lymph nodes from the bronchial hilum;
- D3 mass adjacent to bronchus;
- D4,5 mass to pleura and inked stapled surface including possible confluent lymph nodes;
- D6 mass to pleura;
- D7 uninvolved lung.

The fifth container is labeled "E-left lower lobe anterior vasal tissue," and contains a wedge biopsy of lung tissue measuring 2.2 x 1.5 x 0.8 cm with two stapled edges. The specimen is previously partially incised perpendicular to the stapled edges revealing a central area of fibrosis which measures 1.0 x 0.6 x 0.6 cm. The stapled edges are trimmed and resulting cut surfaces inked blue.

[page 3 of 4]
The specimen is serially sectioned and submitted entirely (with the exception of the stapled edges) in cassettes E1 through E3.

The sixth and final container is received with formalin labeled "F-left lung A\TP window," and contains two probable lymph node fragments measuring 0.5 and 0.7 cm in greatest dimension. The specimen is submitted in toto in a single cassette labeled F1.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Addendum Report

Date Ordered:
Date Complete:
Date Reported:

Addendum Comment

At the request of Dr. _____, a representative portion of this case was sent for EGFR mutation analysis to. This addendum is created only to report those findings.

=====

**MOLECULAR ONCOLOGY
EGFR MUTATION ANALYSIS**

Patient Name:		Case #:
DOB:	_____	Gender: _____
Patient ID #:	SSN: _____	Date Received:
Date Collected:		Client Lab ID #:
Referring Physician:	_____	Hospital ID #:
Treating Physician:		
Client Specimen ID:		
Body Site: Left lung		Specimen(s) Received:
Paraffin embedded tissue		
Clinical Data: Adenocarcinoma		

RESULTS: No mutation detected.

INTERPRETATION:

No mutations were identified; however, 18-20% of patient with non-small-cell lung cancer and without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

COMMENT:

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, the vast majority of mutations are expected to occur in these exons. The analytical sensitivity of the assay is 10-20%, thus mutations present in a low percentage of cells may not be detected.

Most data published to date pertain to gefitinib (Iressa). Similar data have been seen in studies using erlotinib (Tarceva).

[page 4 of 4]
A frequently occurring sequence change 2361 G>A was identified. This polymorphism is not likely to have clinical significance.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

***Electronically Signed ***

[REDACTED]

Taken: [REDACTED]

END OF REPORT.

Source: NCI Genomic Data Commons file 685f209f-f371-41a5-a581-d960c0ff9d09 (TCGA-91-6849.910D922E-8180-48BA-9E13-0F177DC71B2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).